Gene-level copy-number profile of tumor specimen ALCH-B4YR-TTP1-A from ALCHEMIST case ALCH-B4YR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.5 years (23,935 days).
Specimen ALCH-B4YR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6e7a29ce-c1a4-4ab1-84cd-aae6919235a9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4YR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/9105ce5c-7750-4faa-8ff9-e9b6546f6e4e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15; copy number 2: 57,257; copy number 3: 549; copy number 4: 186; copy number 5: 99; copy number 6: 74; copy number 7: 14; copy number 8: 24; copy number 9: 90; copy number 10: 12; copy number 11: 24; copy number 12: 44; copy number 14: 10.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 382 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:710,355–1,728,172, 35 genes, copy number 9–10: ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1.
- chr5:1,931,058–2,119,926, 4 genes, copy number 9: AC126768.3, AC124852.1, AC126768.1, AC126768.2.
- chr8:82,514,568–82,677,153, 1 gene, copy number 9: AC060765.1.
- chr8:84,948,585–85,617,512, 17 genes, copy number 5: ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1.
- chr8:110,899,996–111,040,372, 1 gene, copy number 11 (within-gene range 2–11): LINC01608.
- chr8:111,093,263–113,436,939, 11 genes, copy number 9–11 (within-gene range 2–11): LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:113,432,224–113,433,129, 1 gene, copy number 9: AC055788.2.
- chr8:118,189,455–119,855,894, 24 genes, copy number 5: SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1.
- chr11:95,963,219–103,092,194, 75 genes, copy number 5–12 (within-gene range 5–21) (broad region; genes not listed).
- chr11:103,675,994–105,982,092, 25 genes, copy number 7–9 (within-gene range 2–9): AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, LINC02552, AP001485.1, AP002004.1, CASP12, CASP4LP, CASP4, CASP5, CASP1, CARD16, AP001153.2, CASP1P2, CARD17, CASP1P1, CARD18, OR2AL1P, AP003181.1, Metazoa_SRP, GRIA4, HSPD1P13, RNU4-55P.
- chr11:131,187,022–132,404,060, 12 genes, copy number 5–8 (within-gene range 2–8): AP002856.3, AP002856.1, AP002856.4, AP002856.2, RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP000844.2, AP000844.1, NTM-IT, AP000843.1.
- chr11:133,783,671–134,412,242, 20 genes, copy number 5–10: LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1.
- chr18:31,829,197–32,470,882, 24 genes, copy number 6: TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7.
- chr18:32,511,663–32,582,828, 2 genes, copy number 6: WBP11P1, AC025887.1.
- chr19:29,811,991–29,824,312, 1 gene, copy number 5: CCNE1.
- chr20:53,255,979–53,875,557, 11 genes, copy number 9 (within-gene range 2–9): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1.
- chr20:55,997,357–56,299,160, 5 genes, copy number 6: CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1.
- chr20:57,168,753–59,516,039, 63 genes, copy number 5–9 (broad region; genes not listed).
- chr20:61,077,224–62,776,996, 50 genes, copy number 10–14: AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
